Somatic mutation profile of tumor specimen MMRF_1352_2_BM_CD138pos (aliquot MMRF_1352_2_BM_CD138pos_T1_KBS5U_L05842) from MMRF case MMRF_1352, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.1 years (19,752 days).
Specimen MMRF_1352_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 491fa1e0-251b-4565-b3a2-d391fb8ea2c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1352_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1352_1_PB_Whole_C2_KAS5U_L00669; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56d1a5f3-956f-48f7-910c-28f0364eaf79

The open-access MAF lists 63 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, 3'UTR 20, Intron 10, Silent 7, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1, 3'Flank 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF17 | c.583G>C p.G195R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as rs1238485617; called by mutect2, varscan2
- ATP8B3 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs542432405; called by muse, mutect2, varscan2
- BTBD10 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.022); catalogued as rs766063559; called by muse, mutect2, varscan2
- ERN1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs1202226977; called by mutect2, varscan2
- IGHV2-70 | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs181122105; called by muse, varscan2
- IGHV3-7 | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs371532793; called by muse, mutect2, varscan2
- IGLV3-1 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs762819993; called by muse, mutect2, varscan2
- MUC17 | c.8968A>G p.T2990A | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60283993; called by muse, mutect2, varscan2
- SDF4 | c.303C>A p.S101= | Splice Region (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99767695; called by mutect2, varscan2
- WBP1 | c.411del p.P140Lfs*10 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs1433815904, COSV51970292; called by mutect2, pindel, varscan2*
- ZNF292 | c.6677C>A p.S2226* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV60535205; called by muse, mutect2, varscan2
- AP5M1 | c.1010T>A p.I337K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- EP300 | c.2104A>T p.M702L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- EXOC8 | c.608T>A p.V203E | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM187A | c.885G>T p.E295D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HSPA5 | c.1659A>T p.K553N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); called by mutect2, varscan2
- IGHV2-70D | c.227A>C p.D76A | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- MTA1 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by mutect2, varscan2
- NSD1 | c.3577A>G p.S1193G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHG5 | c.240G>C p.E80D (on ENST00000400915 / NM_001042663.3; = p.E43D on NM_020631.6) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- POU4F1 | c.967A>C p.I323L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- TTC3 | c.2735G>T p.S912I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TYRP1 | c.1577A>C p.Y526S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HSFX1 | c.84T>C p.P28= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, varscan2
- IGDCC4 | c.3594C>A p.T1198= | Silent (SNP) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- IGHJ5 | c.21C>T p.G7= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1407556441; called by muse, varscan2
- ITGA9 | c.705C>T p.N235= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs139839965; called by muse, mutect2, varscan2
- MS4A1 | c.12C>T p.P4= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs202047596, COSV61942926; called by muse, varscan2
- MYO3B | c.2541G>T p.G847= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV100509521; called by muse, mutect2, varscan2
- SMG6 | c.4170G>A p.T1390= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs144129895; called by mutect2, varscan2
- ACER3 | c.*1986G>A | 3'UTR (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- ANKLE2 | c.182-1469C>T | Intron (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- ARL4A | chr7:12689179 T>C | 3'Flank (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2
- CARF | c.832+366T>C | Intron (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- CTNS | c.*912G>A | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, varscan2
- DIP2A | c.*1909A>T | 3'UTR (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- EFNA5 | c.*354_*355del | 3'UTR (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2
- ESYT3 | c.*1232T>A | 3'UTR (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- LINC02207 | n.1938T>C | RNA (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- METAP2 | c.772+11G>A | Intron (SNP) | VAF 6/53 reads (11%) | catalogued as rs1565780753; called by mutect2, varscan2
- MON1B | c.*138C>G | 3'UTR (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- MTHFD2L | c.*1211G>A | 3'UTR (SNP) | VAF 13/75 reads (17%) | catalogued as rs764051816; called by muse, mutect2, varscan2
- PCDH11Y | c.-697T>A | 5'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- PEX1 | c.3439-22A>C | Intron (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- PLCD1 | c.35-4221C>T | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2
- PON3 | c.778-38T>C | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- PSORS1C2 | c.56-271G>C | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- PUDP | c.511-7283G>A | Intron (SNP) | VAF 22/28 reads (79%) | catalogued as rs771236372; called by muse, mutect2, varscan2
- RBM45 | c.989+47T>A | Intron (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- RUSC2 | c.*414C>T | 3'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- RYR2 | c.*9C>G | 3'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- SETD7 | c.*2195G>T | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by mutect2, varscan2
- SFRP1 | c.*64C>T | 3'UTR (SNP) | VAF 7/20 reads (35%) | catalogued as rs1352571037; called by muse, varscan2
- SLC35D1 | c.*4210T>C | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, varscan2
- SLIT3 | c.*2761G>A | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- SOX9 | c.*1336C>T | 3'UTR (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- SPRY3 | c.*7463G>A | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- TADA2B | c.271-954del | Intron (DEL) | VAF 13/50 reads (26%) | called by pindel, varscan2
- TMEM161B | c.*425G>A | 3'UTR (SNP) | VAF 11/75 reads (15%) | called by mutect2, varscan2
- TMPRSS4 | c.*1237A>T | 3'UTR (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- TOR1AIP1 | c.*645A>G | 3'UTR (SNP) | VAF 5/44 reads (11%) | catalogued as rs1261095312; called by muse, mutect2, varscan2
- TPI1 | c.*201A>G | 3'UTR (SNP) | VAF 9/43 reads (21%) | catalogued as rs782508499; called by muse, mutect2, varscan2
- URB1 | c.*1120A>T | 3'UTR (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
